Somatic mutation profile of tumor specimen 0DJXPQ from CCDI case PBBVUY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Alveolar soft part sarcoma; Tissue or organ of origin: Lower limb, NOS; Age at diagnosis: 16.5 years (6,026 days).
Specimen 0DJXPQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b3eb4055-c943-4128-be08-350476a9485f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJXRI (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d077e874-cb3e-4bba-baf1-15d577bc9059

The open-access MAF lists 7 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 2, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GAD2 | c.1342C>T p.R448C | Missense Mutation (SNP) | VAF 119/644 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1263303585; called by muse, mutect2, varscan2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 38/1028 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- ZBTB8OS | c.167C>A p.A56E | Missense Mutation (SNP) | VAF 22/704 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.243); called by muse, mutect2
- KLHL29 | c.1692C>T p.H564= | Silent (SNP) | VAF 196/1117 reads (18%) | catalogued as rs928699381; called by muse, mutect2, varscan2
- OR1N1 | c.816A>T p.A272= | Silent (SNP) | VAF 22/336 reads (7%) | called by muse, mutect2
- AOAH | c.1426-83C>T | Intron (SNP) | VAF 21/66 reads (32%) | catalogued as rs958332480; called by muse, mutect2, varscan2
- GRB7 | c.801+34C>T | Intron (SNP) | VAF 100/420 reads (24%) | catalogued as rs1567928216; called by muse, mutect2, varscan2
